Somatic mutation profile of tumor specimen C3L-05874-54 (aliquot CPT0299880002) from CPTAC case C3L-05874, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 67.7 years (24,733 days).
Specimen C3L-05874-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6405c72-7604-428b-8dbd-f3b784e0b6c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05874-51 (Buccal Cell Normal), aliquot CPT0299870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a6f6c8-2733-4282-a45e-3594fdbf4a1e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SBK3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs770856952; called by muse, mutect2, varscan2
- ADAMTS20 | c.4061G>A p.C1354Y | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR87 | c.7063C>A p.Q2355K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN5 | c.*925A>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
